CCDI case PBBKXH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c4714fdb-feea-4f45-8d5b-d7def32f6e2c

Demographics
Sex at birth: male; Race: asian; Vital status: Dead.

Diagnoses (1)
1. Tumor cells, malignant: ICD-O-3 morphology code: 8001/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 0.5 years (172 days).

Biospecimens (3 samples)
- Sample 0DB97N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB97S: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB97Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
